Surgical pathology report (de-identified scan), TCGA case TCGA-78-7153, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7153-01A (Primary Tumor).

[page 1 of 2]
HISTORY

Large right upper lobe tumour.

MACROSCOPIC

Six specimens received:

1: The specimen is labelled "middle and upper right lobe" and comprises right upper and middle lobe, received fresh, and measuring 160 x 60 x 60 mm. There is a marked degree of pleural puckering and indrawing over the postero-lateral surface of the upper lobe. The pleura overlying the middle lobe appears normal. A stapled margin, 65 mm in length, is present above the hilum. The bronchial resection margins and vascular resection margins show no evidence of tumour. Peribronchial lymph nodes are black and soft. Transverse slicing reveals a somewhat ill-defined tumour mass, 47 mm in diameter, within the postero-lateral aspect of the upper lobe extending almost to the pleural surface and extending to within 10 mm of the bronchial resection margin. The surrounding lung parenchyma appears consolidated and yellowish in colour. The main tumour mass is pale grey to cream in colour with focal carbon pigmentation. The remainder of the lung parenchyma shows no pathological features. Towards the apex of the upper lobe there is a second contiguous lobulated tumour mass, 30 mm in diameter, which also appears clear of the pleura. This has a more tan cut surface. [1A, upper lobe bronchial resection margin and peribronchial lymph nodes; 1B, middle lobe bronchial resection margin and peribronchial lymph nodes; 1C-E, tumour with overlying pleura; 1F, central tumour; 1G, 2 representative TS of additional tumour mass towards apex; 1H, uninvolved lung parenchyma from middle lobe; 1I, tissue adjacent to bronchus].

2: The specimen is labelled "pulmonary vein lymph node" and comprises an irregular portion of fatty and anthracotic soft tissue, 25 x 10 x 5 mm. [BIT, 2A].

3: The specimen is labelled "pulmonary vein lymph node No. 2" and comprises fragments of anthracotic soft tissue, 20 x 10 x 5 mm in aggregate. [BIT, 3A].

4: The specimen is labelled "No. 10 lymph node" and comprises two fragments of soft anthracotic tissue, the first 5 mm in greatest diameter, and the second 15 x 15 x 7 mm. [BIT, the larger fragment after bisection, 4A].

5: The specimen is labelled "right middle lobe lymph node" and comprises an irregular fragment of soft anthracotic tissue, 20 x 8 x 5 mm. [BIT, 5A].

6: The specimen is labelled "No. 4 lymph node" and comprises a lymph node with surrounding fat, overall size 20 x 15 x 8 mm. The lymph node is 12 x 8 x 5 mm. [BIT after bisection, 6A].

MICROSCOPY

1: Sections show a moderately differentiated adenocarcinoma. The carcinoma has areas of mucinous and papillary differentiation. The contiguous nodule has a similar appearance and it is considered that these represent part of the same tumour. The main lesion is invading into an area of subpleural elastotic scarring. Although no convincing pleural invasion is identified within the sections, special stains will be performed. The other component also abuts the pleura but there is no pleural invasion. Blood vessel invasion is present but no lymphatic or perineural permeation is seen. The mass is well clear of the bronchial resection margin but there is squamous metaplasia with severe dysplasia at the middle lobe bronchial resection margin. No lymph node metastases are seen. The uninvolved lung shows no specific abnormality.

2: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

3: Sections of the lymph node fragments show reactive changes only. There is no evidence of malignancy.

4: Sections of the lymph node show reactive changes only. There is no evidence of malignancy.

5: Sections of the lymph node show reactive changes only. There is no evidence of malignancy.

[page 2 of 2]
6: Sections of the lymph node show reactive changes only. There is no evidence of malignancy.

SUMMARY

Right upper and middle lobes and lymph nodes:

- 1: Moderately differentiated adenocarcinoma of right upper lobe; approximately 47 mm in maximal dimension.
- 2: Blood vessel permeation identified but no lymphatic or perineural invasion present.
- 3: No convincing pleural invasion identified but special stains being performed; clear of bronchial margin.
- 4: No lymph node metastases.
- 5: T2N0MX
- 6: Squamous metaplasia with severe dysplasia at right middle lobe bronchial resection margin.

SUPPLEMENTARY REPORT

Some of the tumour cell nuclei stain strongly with TTF 1 in keeping with a pulmonary primary.

SUPPLEMENTARY REPORT

No pleural invasion is identified with special stains.

T-28000 M-81403 P1-03000

Source: NCI Genomic Data Commons file 4bc184ca-a069-4fbd-a634-6b2ca109041b (TCGA-78-7153.14C2A5E1-CEF1-4076-952D-8CF9061BEFFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).